MMRF case MMRF_1542 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cd65fe57-6e09-4436-aa93-6fb784372ef0

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 1,137 days (3.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.3 years (26,395 days); ISS stage: III; Days to last known disease status: 1,137 days (3.1 years); Days to last follow up: 1,137 days (3.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 408 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 1,137 days (3.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 262 days; Days to treatment end: 437 days (1.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 438 days (1.2 years); Days to treatment end: 1,137 days (3.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 520 days (1.4 years); Days to treatment end: 1,137 days (3.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,137.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2751 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.7 mg/dL; Beta 2 Microglobulin 10.8 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 10.6 mmol/L; C-Reactive Protein 500 mg/dL.
- Day 79 (ECOG 0): Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 14 mmol/L.
- Day 156 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Beta 2 Microglobulin 3.36 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 15.6 mmol/L.
- Day 254 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Beta 2 Microglobulin 3.64 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 11.1 mmol/L.
- Day 331 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 8.97 mmol/L.
- Day 429 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 7.98 mmol/L.
- Day 502 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 15.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 1.83 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 8.58 mmol/L.
- Day 597 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 7.1 mmol/L.
- Day 681 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 7.32 mmol/L.

Other clinical attributes
- Day -19: Weight: 79 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_1542_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_1542_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
